Somatic mutation profile of tumor specimen MP2PRT-PAVPAF-TMP1-A (aliquot MP2PRT-PAVPAF-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVPAF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.9 years (5,807 days).
Specimen MP2PRT-PAVPAF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e4064fa-662c-44a4-a754-e3d7770a1672.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVPAF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVPAF-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7360f08-7318-42f9-a2d6-77d32f7e6b95

The open-access MAF lists 18 somatic variants for this specimen: 10 protein-altering or splice-affecting, 8 silent.
By variant classification: Silent 8, Missense Mutation 8, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.5104C>T p.R1702* | Nonsense Mutation (SNP) | VAF 72/453 reads (16%) | catalogued as rs886043414, COSV56407907; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.182A>T p.D61V | Missense Mutation (SNP) | VAF 46/335 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs121918461, CM013415, CM098208, COSV61004983, COSV61005256, COSV61011211; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GAS7 | c.320G>A p.R107H (on ENST00000432992 / NM_201433.2; = p.R47H on NM_201432.2) | Missense Mutation (SNP) | VAF 43/366 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.515); catalogued as rs150719505; called by muse, mutect2, varscan2
- KRT4 | c.1420G>A p.G474R | Missense Mutation (SNP) | VAF 86/509 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.156); catalogued as rs943439676; called by muse, mutect2, varscan2
- MYH8 | c.3166C>T p.R1056W | Missense Mutation (SNP) | VAF 55/422 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1189159212; called by muse, mutect2, varscan2
- NXF1 | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 51/385 reads (13%) | catalogued as rs776538505, COSV53675799; called by muse, mutect2, varscan2
- PRODH2 | c.1538G>A p.R513H (on ENST00000301175; = p.R437H on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/514 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1178283450, COSV99995376; called by muse, mutect2, varscan2
- DSG1 | c.3037G>A p.G1013S | Missense Mutation (SNP) | VAF 77/551 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MIOS | c.130C>G p.R44G | Missense Mutation (SNP) | VAF 51/301 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PPP2R1A | c.1147A>C p.N383H | Missense Mutation (SNP) | VAF 62/332 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- CES1 | c.1107C>T p.S369= (on ENST00000361503 / NM_001025194.2; = p.S368= on NM_001266.5) | Silent (SNP) | VAF 52/354 reads (15%) | catalogued as rs755053782; called by muse, varscan2
- CYP11B2 | c.1155G>T p.V385= | Silent (SNP) | VAF 57/444 reads (13%) | called by muse, mutect2, varscan2
- KRT80 | c.363G>A p.Q121= | Silent (SNP) | VAF 57/398 reads (14%) | catalogued as rs1238221827, COSV57551311; called by muse, mutect2, varscan2
- MLLT3 | c.393T>C p.F131= | Silent (SNP) | VAF 65/300 reads (22%) | catalogued as rs531707287; called by muse, mutect2, varscan2
- NPAS3 | c.2259G>A p.A753= (on ENST00000356141 / NM_001164749.2; = p.A721= on NM_022123.3) | Silent (SNP) | VAF 56/440 reads (13%) | called by muse, mutect2, varscan2
- PCDHB8 | c.2052C>A p.A684= | Silent (SNP) | VAF 112/679 reads (16%) | catalogued as rs373119743, COSV50831214; called by muse, varscan2
- RIPK4 | c.2454C>T p.G818= (on ENST00000352483; = p.G770= on NM_020639.3) | Silent (SNP) | VAF 111/701 reads (16%) | catalogued as rs767725466, COSV100205401; called by muse, mutect2, varscan2
- SEC23A | c.40C>A p.R14= | Silent (SNP) | VAF 27/307 reads (9%) | catalogued as rs768559770, COSV56977618, COSV56978865; called by muse, mutect2
